MMRF case MMRF_2480 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/8c398861-3ccc-43a0-bfc9-67910db50542

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 63 years; Vital status: Dead; Days to death: 141 days; Cause of death: Cancer Related.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 63.9 years (23,329 days); Days to last known disease status: 141 days; Days to last follow up: 141 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 141 days.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 14 days; Days to treatment end: 141 days.

Follow-up (1 entry)
- Follow-up contact recording only the day: day 141.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -19 (ECOG 1): M Protein 3.4 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.02 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 68.2 mg/dL; Lactate Dehydrogenase 3.3 µkat/L; Hemoglobin 6.94 mmol/L; Leukocytes 4.7 ×10⁹/L; Platelets 128 ×10⁹/L; Creatinine 177 µmol/L; Blood Urea Nitrogen 8.21 mmol/L; Calcium 2.28 mmol/L; Albumin 26 g/L; Total Protein 9.2 g/dL; Glucose 7.1 mmol/L.
- Day 78 (ECOG 2): Serum Free Immunoglobulin Light Chain, Kappa 2.03 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 52.7 mg/dL; Lactate Dehydrogenase 3.83 µkat/L; Hemoglobin 6.26 mmol/L; Leukocytes 6.6 ×10⁹/L; Absolute Neutrophil 5.7 ×10⁹/L; Platelets 106 ×10⁹/L; Creatinine 141 µmol/L; Blood Urea Nitrogen 7.14 mmol/L; Calcium 1.88 mmol/L; Albumin 24 g/L; Total Protein 7.6 g/dL; Glucose 10.1 mmol/L.
- Day 120 (ECOG 2): Serum Free Immunoglobulin Light Chain, Kappa 2.58 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 13.6 mg/dL; Lactate Dehydrogenase 3.22 µkat/L; Hemoglobin 6.57 mmol/L; Leukocytes 11.5 ×10⁹/L; Absolute Neutrophil 9.3 ×10⁹/L; Platelets 71 ×10⁹/L; Creatinine 177 µmol/L; Blood Urea Nitrogen 13.6 mmol/L; Calcium 2 mmol/L; Albumin 24 g/L; Total Protein 7.8 g/dL; Glucose 9.79 mmol/L.

Other clinical attributes
- Day -19: Weight: 79 kg; Height: 162 cm.

Family history
- Relative with cancer history: no.

Biospecimens (2 samples)
- Sample MMRF_2480_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -19 days.
- Sample MMRF_2480_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -19 days.
